Surgical pathology report (de-identified scan), TCGA case TCGA-BJ-A3PU, project TCGA-THCA (Thyroid Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BJ-A3PU-01A (Primary Tumor).

Collection Date:

FINAL DIAGNOSIS:

PART 1: CONTENTS, CENTRAL COMPARTMENT, EXCISION -

- SIX OF SIX LYMPH NODES POSITIVE FOR METASTATIC PAPILLARY THYROID CARCINOMA (6/6).
- PARATHYROID PROFILE (1).

PART 2: THYROID, TOTAL THYROIDECTOMY -

- PAPILLARY THYROID CARCINOMA, FOLLICULAR VARIANT, OF LEFT LOBE, 2.6 CM.
- CARCINOMA INVADERS PERI-THYROIDAL SOFT TISSUE.
- CARCINOMA FOCALLY INVOLVES THE SKELETAL MUSCLE.
- LYMPHOVASCULAR INVASION IDENTIFIED.
- CARCINOMA EXTENSIVELY PRESENT AT THE PERIPHERAL SURGICAL MARGINS.
- ONE CENTRAL LYMPH NODE, POSITIVE FOR METASTATIC PAPILLARY THYROID CARCINOMA (1/1).
- TNM STAGE (AJCC, 7th Edition): p T3 N1

PART 3: PARATHYROID, LEFT SUPERIOR, BIOPSY - NORMOCYLLULAR PARATHYROID TISSUE, 20 MILLIGRAMS.

COMMENT:

Selected slides of part 2 of this case are also reviewed by Dr.

who agrees with the diagnosis.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY THYROID TUMORS

SPECIMEN TYPE:	Total Thyroidectomy
TUMOR SITE:	Left Lobe
TUMOR FOCALITY:	Unifocal
TUMOR SIZE (largest nodule):	Greatest Dimension: 2.6 cm Additional Dimensions: 2.0 cm
HISTOLOGIC TYPE**:	Papillary carcinoma
PRIMARY TUMOR (pT):	pT3
REGIONAL LYMPH NODES (pN):	pN1a Number of regional lymph nodes examined: 7 Number of regional lymph nodes involved: 7
EXTRANODAL EXTENSION:	Not identified
DISTANT METASTASIS (pM):	Not applicable
EXTRATHYROIDAL EXTENSION:	Present
MARGINS:	Margin(s) Involved by carcinoma
LYMPH-VASCULAR INVASION:	Present
ADDITIONAL PATHOLOGIC FINDINGS:	None Identified

ADDENDA:

Addendum

This addendum is to clarify the diagnosis in part 2 of this case.

The first line of the diagnosis should read: PAPILLARY THYROID CARCINOMA, OF LEFT LOBE, 2.6 CM.

ICD-0-3

Carcinoma, papillary, thyroid 8260/3

Site: thyroid, NOS C73.9

FIPIAA Discrepancy		☒
	3/9/12	

Source: NCI Genomic Data Commons file f5f68421-2243-4719-8283-6ea6a84bbcb7 (TCGA-BJ-A3PU.32481AD7-2C27-408C-81AF-FB53FF84DB25.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).